Somatic mutation profile of tumor specimen TCGA-CI-6624-01C (aliquot TCGA-CI-6624-01C-11D-1826-10) from TCGA case TCGA-CI-6624, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.2 years (19,419 days).
Specimen TCGA-CI-6624-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4ea64bb-8dbb-47e8-9a96-cc6abb57edcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CI-6624-10A (Blood Derived Normal), aliquot TCGA-CI-6624-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6a18e11-af43-4fd1-a705-bf4233d90d27

The open-access MAF lists 288 somatic variants for this specimen: 223 protein-altering or splice-affecting, 60 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 60, Nonsense Mutation 13, Frame Shift Del 3, Intron 2, Splice Site 2, RNA 2, Splice Region 2, Frame Shift Ins 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TTN | c.99164del p.P33055Qfs*51 (on ENST00000591111; = p.P25631Qfs*51 on NM_003319.4) | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | catalogued as rs1553489404; ClinVar: likely pathogenic; called by pindel, varscan2
- A2M | c.2314C>A p.L772M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV59388351; called by muse, mutect2, varscan2
- ABCC10 | c.1133G>A p.G378E (on ENST00000372530 / NM_001198934.2; = p.G335E on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55089363; called by muse, mutect2, varscan2
- ABCC11 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs138453043; called by muse, mutect2, varscan2
- ACOXL | c.1219C>A p.Q407K (on ENST00000389811 / NM_001371254.1; = p.Q377K on NM_001142807.4) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV67736711; called by muse, mutect2, varscan2
- ACSL3 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62483043; called by muse, mutect2, varscan2
- ADCY7 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746905825, COSV54267775; called by muse, mutect2, varscan2
- ADGRB1 | c.3065T>A p.F1022Y | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV60098508; called by muse, mutect2, varscan2
- ADH5 | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 29/108 reads (27%) | catalogued as COSV56448353; called by muse, mutect2, varscan2
- ADRB3 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs759812310, COSV61462162; called by muse, mutect2, varscan2
- AGBL1 | c.2069A>G p.Y690C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66861698; called by muse, mutect2, varscan2
- AGGF1 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57229647, COSV57229798; called by muse, mutect2, varscan2
- AKAP11 | c.5196C>A p.S1732R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99213734, COSV99214357; called by muse, mutect2, varscan2
- AKAP8L | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV101275773; called by muse, mutect2, varscan2
- ALDH3A2 | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as rs1288402141, COSV51567247; called by muse, mutect2, varscan2
- ALX4 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV61325065, COSV61327067; called by muse, mutect2, varscan2
- ALX4 | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.04); catalogued as rs1000997080, COSV100240987; called by mutect2, varscan2
- AR | c.588A>C p.Q196H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV65958447; called by muse, mutect2, varscan2
- ARHGAP33 | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); catalogued as COSV50127110; called by muse, mutect2
- ARSI | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV60817725; called by muse, mutect2, varscan2
- ASH1L | c.8107C>T p.R2703C (on ENST00000368346 / NM_001366177.2; = p.R2698C on NM_018489.3) | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1001568799, COSV100853303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATG9B | c.628T>A p.C210S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV52506070; called by muse, mutect2, varscan2
- ATP11B | c.1444-1G>C p.X482_splice | Splice Site (SNP) | VAF 24/94 reads (26%) | catalogued as COSV60029744; called by mutect2, varscan2
- BAZ1B | c.2242A>T p.I748F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV59992010; called by muse, mutect2, varscan2
- BIRC3 | c.1811C>A p.S604* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV99679818; called by muse, mutect2
- BRCA2 | c.3286G>A p.D1096N | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV101204106; called by muse, mutect2
- BRCA2 | c.3288T>G p.D1096E | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV101204107; called by muse, mutect2
- BRCC3 | c.935T>A p.L312H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57462818; called by muse, mutect2, varscan2
- BVES | c.797A>T p.D266V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV58948437; called by muse, mutect2, varscan2
- CACNA2D3 | c.3123A>T p.E1041D | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55549731; called by muse, mutect2, varscan2
- CACNA2D4 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347668261, COSV54952230; called by muse, mutect2, varscan2
- CAMSAP2 | c.1931C>T p.T644I (on ENST00000236925 / NM_001297707.2; = p.T633I on NM_203459.3) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV99373155; called by muse, mutect2
- CBX1 | c.555C>A p.N185K | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV56682095; called by muse, mutect2, varscan2
- CCDC88A | c.1937A>G p.K646R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as COSV55063839; called by muse, mutect2, varscan2
- CD1E | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100937010, COSV63770217; called by muse, mutect2, varscan2
- CDH9 | c.650T>G p.I217R | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50305350; called by muse, mutect2, varscan2
- CDK15 | c.618T>A p.F206L (on ENST00000652192 / NM_001366386.2; = p.F155L on NM_139158.2) | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53635490; called by muse, mutect2, varscan2
- CELSR2 | c.7720G>A p.A2574T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.713); catalogued as rs751045325, COSV54774032; called by muse, mutect2, varscan2
- CEP164 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1216610724, COSV54042568; called by muse, mutect2, varscan2
- CHD1 | c.3295G>C p.D1099H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52338928, COSV52341599; called by muse, mutect2, varscan2
- CLEC18B | c.1289A>G p.D430G | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100375869; called by muse, mutect2, varscan2
- CNOT10 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59392747; called by muse, mutect2, varscan2
- CNTNAP5 | c.1361G>C p.S454T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV101443311; called by muse, mutect2
- COBLL1 | c.1804G>T p.V602F (on ENST00000392717; = p.V564F on NM_014900.5) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs754250437, COSV52069837; called by muse, mutect2, varscan2
- CPS1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV99242643; called by muse, mutect2, varscan2
- CPXM1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as rs746775795, COSV66045852; called by muse, mutect2
- CRYL1 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs200561765; called by muse, mutect2, varscan2
- CSMD3 | c.9410T>A p.V3137D (on ENST00000297405 / NM_001363185.1; = p.V2968D on NM_052900.3) | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52122823, COSV52213789; called by muse, varscan2
- CWF19L2 | c.2154C>A p.H718Q | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56514387; called by muse, mutect2, varscan2
- DENND5A | c.2776G>A p.E926K | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV60234819; called by muse, mutect2, varscan2
- DIAPH3 | c.878C>T p.S293F (on ENST00000400324 / NM_001042517.2; = p.S30F on NM_030932.3) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57372596; called by muse, mutect2
- DNAH11 | c.4670G>T p.R1557L | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1166407911, COSV100178473, COSV60966002; called by muse, mutect2, varscan2
- DSCAM | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.2); catalogued as rs1271387824, COSV68643794, COSV68646436; called by muse, mutect2, varscan2
- EDA | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.085); catalogued as rs1237632459, COSV65771005, COSV65773696; called by muse, mutect2, varscan2
- EFCAB5 | c.4339G>C p.V1447L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs1244550673, COSV57931863; called by muse, mutect2, varscan2
- EGFLAM | c.2867G>A p.R956Q (on ENST00000354891 / NM_001205301.2; = p.R948Q on NM_152403.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs772568999, COSV59306213; called by muse, mutect2, varscan2
- ELOC | c.5-1G>C p.X2_splice | Splice Site (SNP) | VAF 111/346 reads (32%) | catalogued as COSV53023334; called by muse, mutect2, varscan2
- EML2 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV55600686; called by muse, mutect2, varscan2
- EPHA6 | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV67577489; called by mutect2, varscan2
- FAM20A | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as COSV99873275; called by muse, mutect2
- FAT3 | c.1546T>A p.L516M | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV53127494; called by muse, mutect2, varscan2
- FCRL3 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.085); catalogued as rs753184362, COSV63842572; called by muse, mutect2, varscan2
- FIBCD1 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs752523144, COSV99446923; called by mutect2, varscan2
- FLNA | c.3699C>G p.I1233M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV61043030, COSV61045599; called by muse, mutect2, varscan2
- FLT3 | c.2161C>A p.H721N | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as COSV54058056; called by muse, mutect2
- FLT4 | c.503C>G p.T168R | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs148392893, COSV56112199, COSV56119760; called by muse, mutect2, varscan2
- FMNL2 | c.2338C>A p.Q780K | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.561); catalogued as COSV56497517; called by muse, mutect2, varscan2
- FMO3 | c.1473C>A p.D491E | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV63007655; called by muse, mutect2
- FRMPD1 | c.1805C>A p.T602N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100899516; called by muse, mutect2, varscan2
- GALM | c.781C>T p.H261Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1304841449, COSV99697113; called by muse, mutect2
- GALNT13 | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67225307; called by muse, mutect2, varscan2
- GFM2 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.028); catalogued as COSV57191526; called by muse, mutect2, varscan2
- GPR101 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.049); catalogued as COSV53239305, COSV99035716; called by muse, mutect2, varscan2
- GRAMD1A | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV58767509; called by muse, mutect2, varscan2
- GRIA1 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1194364279, COSV53597870; called by muse, mutect2, varscan2
- GRIK3 | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs373548070, COSV66141490; called by muse, mutect2, varscan2
- HDAC9 | c.2900C>A p.A967D | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV67775997; called by muse, mutect2, varscan2
- HEATR5B | c.3808T>A p.F1270I | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99248882; called by muse, mutect2, varscan2
- HECW1 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV67832230; called by muse, mutect2
- HECW2 | c.3049C>T p.R1017W | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1395802562, COSV53659589; called by muse, mutect2, varscan2
- HRH2 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs141845922; called by muse, mutect2, varscan2
- HS3ST3B1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100714503; called by muse, mutect2, varscan2
- IGHD | c.893G>A p.G298D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as COSV101162833; called by muse, mutect2, varscan2
- IKZF1 | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV100498265; called by muse, mutect2, varscan2
- IL17RC | c.983C>T p.P328L (on ENST00000295981 / NM_153461.4; = p.P242L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs764646516, COSV55973641; called by mutect2, varscan2
- IL1RAP | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.177); catalogued as COSV50763805; called by muse, mutect2, varscan2
- IL1RL2 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV51816205; called by muse, mutect2, varscan2
- IPO11 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57577512; called by muse, mutect2, varscan2
- KCNK16 | c.882A>T p.Q294H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV64678413; called by muse, mutect2, varscan2
- KIAA1328 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99693909; called by muse, mutect2, varscan2
- KLRC4 | c.73A>C p.K25Q | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58672005; called by muse, mutect2, varscan2
- LARS1 | c.502G>A p.D168N (on ENST00000394434 / NM_020117.11; = p.D141N on NM_016460.3) | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.275); catalogued as rs767396724, COSV99198537; called by muse, mutect2, varscan2
- LATS1 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs760569700, COSV53593090; called by muse, mutect2, varscan2
- LCA5 | c.1339C>G p.P447A | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV63971785; called by muse, mutect2, varscan2
- LRP1B | c.1766A>G p.E589G | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101255019; called by muse, mutect2, varscan2
- LRP2 | c.10153C>T p.H3385Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1379215552, COSV99787548; called by muse, mutect2, varscan2
- LRRIQ1 | c.1749A>G p.I583M | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV67832676; called by muse, mutect2, varscan2
- LRRIQ3 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV63045416; called by muse, varscan2
- MAD1L1 | c.1662G>T p.R554S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV56238067; called by muse, mutect2, varscan2
- MAGEC1 | c.3295T>A p.F1099I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV53575172; called by muse, mutect2, varscan2
- MAGEL2 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV58567659; called by muse, mutect2, varscan2
- MAP2K3 | c.505A>T p.I169F (on ENST00000342679 / NM_145109.3; = p.I140F on NM_002756.4) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV100383683; called by muse, mutect2
- MAP4K3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.055); catalogued as COSV99810217; called by muse, mutect2
- MBTPS2 | c.1124A>C p.K375T | Missense Mutation (SNP) | VAF 28/260 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101068386; called by muse, mutect2, varscan2
- MDFIC | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs764638487, COSV57564726; called by muse, mutect2, varscan2
- MED1 | c.2098C>A p.P700T | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV56125918; called by muse, mutect2, varscan2
- MED12L | c.3733T>C p.Y1245H | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV56383259; called by muse, mutect2, varscan2
- MFSD1 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51841453; called by muse, mutect2, varscan2
- MFSD6 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 35/176 reads (20%) | catalogued as COSV55623328; called by muse, mutect2, varscan2
- MITF | c.560A>C p.N187T (on ENST00000448226 / NM_006722.3; = p.N81T on NM_000248.4) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as COSV58830072; called by muse, mutect2
- MKI67 | c.4137A>T p.E1379D | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.828); catalogued as COSV100896869, COSV64075066; called by muse, mutect2, varscan2
- MMRN2 | c.1502T>A p.L501Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV64400876; called by muse, mutect2, varscan2
- MSH4 | c.34T>A p.S12T | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); catalogued as COSV54205034; called by muse, mutect2, varscan2
- MYH1 | c.4132A>C p.K1378Q | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56850726; called by muse, mutect2, varscan2
- NAA25 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55702792; called by muse, mutect2, varscan2
- NCAM1 | c.54T>G p.V18= | Splice Region (SNP) | VAF 6/46 reads (13%) | catalogued as rs782696265, COSV57518650; called by muse, mutect2, varscan2
- NEK10 | c.1773C>G p.Y591* | Nonsense Mutation (SNP) | VAF 18/192 reads (9%) | catalogued as COSV100411662; called by muse, mutect2, varscan2
- NELL2 | c.1612G>A p.A538T | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs562088318, COSV61577484; called by muse, mutect2, varscan2
- NRK | c.4217T>A p.L1406H | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV54599115; called by muse, mutect2, varscan2
- NT5C2 | c.331A>C p.K111Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58417142; called by muse, mutect2, varscan2
- NUP88 | c.1302T>G p.D434E | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV56706106; called by muse, mutect2
- NXPE4 | c.409T>G p.F137V | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV64943941; called by muse, mutect2, varscan2
- NYAP1 | c.2225A>T p.H742L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100278428; called by muse, mutect2
- NYAP2 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV56008410; called by muse, mutect2, varscan2
- OBSCN | c.7927C>T p.R2643* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs867564554, COSV52763961; called by muse, mutect2, varscan2
- OR2M2 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as COSV62898353, COSV62898618; called by muse, mutect2
- OR4A15 | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV59035857; called by muse, mutect2, varscan2
- OR51B2 | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV60916985; called by muse, mutect2, varscan2
- OR52W1 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs146972287; called by muse, mutect2, varscan2
- OR5AP2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.338); catalogued as COSV57257872; called by muse, mutect2, varscan2
- OR9Q1 | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100109709; called by muse, mutect2, varscan2
- PAPOLB | c.782A>T p.Y261F | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV68201748; called by muse, mutect2, varscan2
- PAPPA2 | c.4078T>A p.S1360T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV62800811; called by muse, mutect2, varscan2
- PARP11 | c.119C>A p.A40E | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV57395614; called by muse, mutect2, varscan2
- PCDH17 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.606); catalogued as COSV100931549; called by muse, mutect2, varscan2
- PCDHGA9 | c.885T>G p.N295K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.082); catalogued as COSV53968855; called by muse, mutect2, varscan2
- PDE3B | c.2081G>C p.R694T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as COSV56385499, COSV56391340; called by muse, mutect2, varscan2
- PDPR | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 33/588 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV99848068; called by muse, mutect2
- PHKA2 | c.16A>C p.N6H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV66054605; called by muse, mutect2, varscan2
- PKDREJ | c.4461C>A p.Y1487* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV53550039; called by muse, mutect2, varscan2
- PRG4 | c.3623C>G p.T1208S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63355801, COSV63356045; called by muse, mutect2, varscan2
- PTPRT | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs751972373, COSV61965149; called by muse, mutect2, varscan2
- PTRHD1 | c.278A>C p.E93A | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99578902; called by mutect2, varscan2
- QSER1 | c.3442G>C p.G1148R (on ENST00000399302; = p.G1277R on NM_001076786.3) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67900951; called by muse, mutect2, varscan2
- RAD51AP2 | c.276A>C p.K92N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.404); catalogued as COSV67588278; called by muse, mutect2, varscan2
- RASD2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs764653107, COSV53352757; called by muse, mutect2, varscan2
- RESF1 | c.1093G>C p.A365P | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV57023064; called by muse, mutect2, varscan2
- RND3 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as COSV99811960; called by muse, mutect2, varscan2
- RSAD2 | c.898T>A p.S300T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65908479; called by muse, mutect2, varscan2
- RYR3 | c.13136A>T p.K4379M (on ENST00000389232; = p.K4380M on NM_001036.6) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV101212423; called by muse, mutect2, varscan2
- SCAPER | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57742922; called by muse, mutect2, varscan2
- SEC24B | c.379G>C p.V127L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV54501612; called by muse, mutect2, varscan2
- SERPINB7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs756029823, COSV100320421, COSV60534448; called by muse, varscan2
- SFMBT2 | c.867T>G p.F289L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1277721055, COSV62811323; called by muse, mutect2, varscan2
- SIGLEC1 | c.3842G>T p.C1281F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163867; called by muse, mutect2
- SIK2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs200775925, COSV100515922; called by muse, varscan2
- SLC12A4 | c.2831C>T p.T944I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV50453060; called by muse, mutect2, varscan2
- SLC13A3 | c.1462A>G p.I488V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV51717732; called by mutect2, varscan2
- SLC15A4 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV57162034; called by muse, mutect2, varscan2
- SLC16A7 | c.796A>T p.I266L | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV53896262; called by muse, mutect2, varscan2
- SLC35B3 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467683, COSV59470231; called by muse, mutect2, varscan2
- SLITRK3 | c.1892A>C p.H631P | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53849524; called by muse, mutect2, varscan2
- SLITRK5 | c.753C>A p.D251E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61523582; called by muse, mutect2, varscan2
- SMARCA5 | c.1300A>G p.I434V | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99303672; called by muse, mutect2, varscan2
- SMARCA5 | c.1869G>T p.M623I | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51645224; called by muse, mutect2, varscan2
- SNX15 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs201908657, COSV57247357; called by muse, mutect2, varscan2
- SPTBN2 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59454377; called by muse, mutect2, varscan2
- STAG1 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.141); catalogued as COSV52613522; called by muse, mutect2
- STAT1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV100699979; called by muse, mutect2, varscan2
- SUCO | c.3656T>C p.L1219P | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV55262824, COSV55266852; called by muse, mutect2, varscan2
- SYNE1 | c.14552A>C p.Y4851S (on ENST00000367255 / NM_182961.4; = p.Y4780S on NM_033071.3) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as COSV99559154; called by muse, mutect2, varscan2
- SYNPO2 | c.1376T>A p.V459D | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV61112879; called by muse, mutect2, varscan2
- TAB3 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 17/139 reads (12%) | catalogued as rs770225305, COSV55834244; called by muse, mutect2, varscan2
- TARS3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV100254472, COSV60108103; called by muse, mutect2, varscan2
- TAS2R30 | c.419T>A p.L140* | Nonsense Mutation (SNP) | VAF 44/133 reads (33%) | catalogued as COSV67857306; called by muse, mutect2, varscan2
- TERF1 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52578329; called by muse, mutect2
- TEX14 | c.4145A>C p.E1382A (on ENST00000240361 / NM_001201457.2; = p.E1336A on NM_031272.5) | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV53619449; called by muse, mutect2
- TF | c.1357A>T p.K453* | Nonsense Mutation (SNP) | VAF 20/162 reads (12%) | catalogued as COSV53921324; called by muse, mutect2, varscan2
- TFEB | c.1303C>G p.L435V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.767); catalogued as COSV100026105; called by muse, mutect2, varscan2
- TG | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs773694618, COSV55080990, COSV99601042; called by muse, mutect2, varscan2
- TIE1 | c.2907C>A p.Y969* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV65250131; called by muse, mutect2, varscan2
- TMEM132E | c.2080C>T p.R694C (on ENST00000321639; = p.R784C on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1318148313, COSV58695915; called by muse, varscan2
- TMEM74 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99865573; called by muse, mutect2
- TMEM87B | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs760225430, COSV51716047; called by muse, mutect2, varscan2
- TPK1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63642460; called by muse, mutect2, varscan2
- TRIM39 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.428); catalogued as COSV100935686; called by muse, mutect2
- TRPC4 | c.1172A>T p.D391V | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV59004225; called by muse, mutect2
- TRPC6 | c.2551C>G p.P851A | Missense Mutation (SNP) | VAF 24/320 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV100723547; called by muse, mutect2
- TRPV6 | c.708A>T p.G236= | Splice Region (SNP) | VAF 27/143 reads (19%) | catalogued as COSV63892173; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- TUT4 | c.2854G>C p.D952H | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV57115597; called by muse, mutect2, varscan2
- UGT2A3 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs770995000, COSV52360647, COSV52360935; called by muse, mutect2, varscan2
- ULK2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV100860716; called by muse, mutect2, varscan2
- UNC13C | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs759219393, COSV52886505; called by muse, mutect2, varscan2
- USH2A | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080595, COSV56330658, COSV56386823, COSV56410469; called by muse, mutect2, varscan2
- USP19 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV60046636; called by muse, mutect2
- UTRN | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.345); catalogued as COSV62338628; called by muse, mutect2, varscan2
- WDHD1 | c.2195C>T p.S732L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV62214424; called by muse, mutect2, varscan2
- WDR64 | c.1983G>C p.L661F | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.937); catalogued as COSV100843742, COSV63796997; called by muse, mutect2, varscan2
- WDSUB1 | c.997T>A p.S333T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.865); catalogued as COSV63067494; called by muse, mutect2, varscan2
- WSCD2 | c.1410G>C p.K470N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54584823; called by muse, mutect2, varscan2
- XIRP2 | c.1982C>A p.T661K (on ENST00000628543; = p.T836K on NM_152381.6) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV54709485; called by muse, mutect2, varscan2
- ZMYM3 | c.2911T>G p.F971V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV100077678; called by muse, mutect2, varscan2
- ZNF131 | c.374A>G p.N125S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.111); catalogued as COSV100185343; called by muse, mutect2
- ZNF215 | c.1022T>G p.F341C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV99549459; called by muse, mutect2, varscan2
- ZNF543 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV58627553, COSV58627977; called by muse, mutect2, varscan2
- ZNF644 | c.3277T>G p.L1093V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100494367; called by muse, mutect2, varscan2
- ZNF689 | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV54908909; called by muse, mutect2, varscan2
- ZNF692 | c.1233C>G p.H411Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60638162; called by muse, mutect2, varscan2
- ZNF839 | c.1031A>T p.E344V (on ENST00000558850 / NM_001267827.1; = p.E460V on NM_018335.5) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV51757947; called by muse, mutect2, varscan2
- ZNF85 | c.374A>G p.K125R | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV56021564, COSV56022043; called by muse, mutect2, varscan2
- ZNF98 | c.353A>G p.E118G | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100757387; called by muse, mutect2, varscan2
- ZNFX1 | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV65576283; called by muse, mutect2
- ZPBP | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV99249454; called by muse, mutect2
- CCL4 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FCGBP | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GTSF1 | c.158_180del p.F53Sfs*3 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel
- MTA3 | c.919dup p.I307Nfs*2 | Frame Shift Ins (INS) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- SAP30BP | c.153_154del p.R53Sfs*4 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel, varscan2
- ZC3H18 | c.1753_1770del p.R585_S590del | In Frame Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel
- ADCY3 | c.552C>A p.P184= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as COSV53168809; called by muse, mutect2, varscan2
- CAMK1D | c.747C>T p.S249= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs774341330, COSV66613868; called by muse, mutect2, varscan2
- CCDC50 | c.612G>T p.L204= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as COSV66668513; called by muse, mutect2, varscan2
- CD22 | c.228C>T p.L76= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs139372163; called by mutect2, varscan2
- CNTN6 | c.2223G>C p.R741= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100610455; called by muse, mutect2
- COL4A2 | c.228A>C p.G76= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV64629661; called by muse, mutect2, varscan2
- CSMD2 | c.1887T>C p.F629= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV99588365; called by muse, mutect2, varscan2
- DCT | c.1059G>T p.G353= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV65469673; called by muse, mutect2, varscan2
- DDX60L | c.3480A>T p.T1160= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV52715568; called by muse, mutect2, varscan2
- DGKD | c.2271T>C p.Y757= (on ENST00000264057 / NM_152879.3; = p.Y713= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99895973; called by muse, mutect2, varscan2
- DNAH10 | c.10224G>A p.K3408= (on ENST00000409039; = p.K3347= on NM_207437.3) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1436794369, COSV68995622; called by muse, varscan2
- DNAH11 | c.11037C>A p.T3679= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV100178475; called by muse, mutect2, varscan2
- DSCAM | c.2601T>C p.A867= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs367614504; called by muse, mutect2, varscan2
- DUS1L | c.1110G>A p.K370= | Silent (SNP) | VAF 30/165 reads (18%) | catalogued as COSV57649660; called by muse, mutect2, varscan2
- EIF3I | c.339C>T p.D113= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV59084676; called by muse, mutect2, varscan2
- ENPP7 | c.156C>T p.P52= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV60386963; called by muse, mutect2, varscan2
- EYA2 | c.1119C>A p.G373= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100426669; called by mutect2, varscan2
- FAT2 | c.2121T>C p.I707= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV55822254; called by muse, mutect2, varscan2
- FLG | c.2535G>A p.P845= | Silent (SNP) | VAF 35/306 reads (11%) | catalogued as rs148002225; called by muse, mutect2, varscan2
- FOXI1 | c.621C>T p.F207= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs532647880, COSV60387918; called by muse, mutect2, varscan2
- GNL3L | c.1227G>C p.L409= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV60576789, COSV60577845; called by muse, mutect2, varscan2
- GPR101 | c.570C>G p.P190= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV53239290, COSV99981414; called by muse, mutect2, varscan2
- GRIN3A | c.1293A>G p.Q431= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as COSV100701440; called by muse, mutect2, varscan2
- HAO1 | c.679A>C p.R227= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV101113168; called by mutect2, varscan2
- HERC1 | c.2028T>C p.H676= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV71248486; called by muse, mutect2, varscan2
- HERC2 | c.9366C>T p.T3122= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV55329548; called by muse, mutect2, varscan2
- KIAA1586 | c.849T>C p.N283= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV66056863; called by muse, mutect2, varscan2
- LAMP1 | c.846C>T p.G282= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs777585404, COSV58150549; called by mutect2, varscan2
- LRP1B | c.2622C>T p.S874= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs775728525, COSV63341565; called by muse, mutect2
- MST1 | c.483T>C p.T161= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV56534339; called by muse, mutect2, varscan2
- NBEAL2 | c.4344C>T p.N1448= | Silent (SNP) | VAF 58/194 reads (30%) | catalogued as rs781019108, COSV52759544; called by muse, mutect2, varscan2
- NCBP1 | c.2046C>T p.D682= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV64307697; called by muse, mutect2, varscan2
- OR4D2 | c.288C>T p.G96= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV73459751; called by muse, mutect2, varscan2
- OR5D13 | c.285T>A p.S95= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV62334157, COSV62335212; called by muse, mutect2, varscan2
- OR5H1 | c.94T>C p.L32= | Silent (SNP) | VAF 56/359 reads (16%) | catalogued as COSV100641609, COSV63402638; called by muse, mutect2, varscan2
- P2RY6 | c.129G>A p.L43= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs1439940499, COSV62936980; called by muse, mutect2, varscan2
- PCDH7 | c.435G>A p.S145= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV62340201; called by muse, mutect2, varscan2
- PHF3 | c.2481C>G p.V827= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV50322557; called by muse, mutect2, varscan2
- PHTF2 | c.1584C>G p.L528= (on ENST00000248550 / NM_001366089.1; = p.L490= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as COSV50329918; called by muse, mutect2, varscan2
- PIK3R1 | c.267C>T p.P89= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as rs766793298, COSV99142295; called by muse, mutect2, varscan2
- PNLIPRP3 | c.183A>C p.I61= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100982440; called by muse, mutect2, varscan2
- POU3F4 | c.684G>A p.S228= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs1467436175, COSV64539685; called by muse, mutect2, varscan2
- PPP6R3 | c.888T>C p.H296= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV55729335; called by muse, mutect2, varscan2
- PRDM9 | c.2436C>G p.G812= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV57008118; called by muse, mutect2, varscan2
- RBMS3 | c.1119T>C p.P373= (on ENST00000383767 / NM_001003793.3; = p.P357= on NM_014483.3) | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV56151186; called by muse, mutect2, varscan2
- REG4 | c.312G>A p.Q104= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56653452; called by muse, mutect2, varscan2
- SLC22A2 | c.84G>A p.L28= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- SLCO6A1 | c.1605T>C p.S535= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV65811514; called by muse, mutect2, varscan2
- SNCAIP | c.180G>A p.T60= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs754791570, COSV54412962; called by muse, mutect2, varscan2
- SPEG | c.7644C>T p.G2548= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV56672060; called by muse, mutect2, varscan2
- SPIB | c.684G>A p.A228= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV54531336; called by muse, mutect2, varscan2
- SYCP2 | c.1866A>G p.T622= | Silent (SNP) | VAF 20/238 reads (8%) | catalogued as rs750218973, COSV62769305; called by muse, mutect2
- TCTEX1D2 | c.288G>C p.V96= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV57488697; called by muse, mutect2, varscan2
- TEX10 | c.1647C>G p.S549= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100887676; called by mutect2, varscan2
- TMPRSS3 | c.807C>T p.T269= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52304247; called by muse, mutect2, varscan2
- TNR | c.3360C>T p.I1120= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- TTN | c.9066A>G p.T3022= (on ENST00000591111; = p.T2976= on NM_003319.4) | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV60137085; called by muse, mutect2, varscan2
- ZFHX4 | c.1488T>A p.G496= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51443784; called by muse, mutect2, varscan2
- ZNF786 | c.2271C>T p.S757= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100302776; called by muse, mutect2, varscan2
- ZWINT | c.732T>C p.T244= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100571498; called by muse, varscan2
- ASIC2 | c.556-179695G>A | Intron (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56764579; called by muse, mutect2, varscan2
- DCHS2 | n.3498T>C | RNA (SNP) | VAF 20/155 reads (13%) | catalogued as COSV100251451; called by muse, mutect2, varscan2
- MAF | c.*4261G>A | 3'UTR (SNP) | VAF 23/75 reads (31%) | catalogued as COSV58154637; called by muse, mutect2, varscan2
- TTN | c.34264+560A>G | Intron (SNP) | VAF 14/111 reads (13%) | catalogued as COSV60137068; called by muse, mutect2, varscan2
- UBTFL2 | n.870G>C | RNA (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
